Somatic mutation profile of tumor specimen MMRF_2173_1_BM_CD138pos (aliquot MMRF_2173_1_BM_CD138pos_T1_KHS5U_L08726) from MMRF case MMRF_2173, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.2 years (27,451 days).
Specimen MMRF_2173_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e24aa337-26b2-4fc8-8ed2-b2c859bf59f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2173_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2173_1_PB_Whole_C3_KHS5U_L08725; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d3bd89e-7d05-4e3e-990d-506b0b744ebe

The open-access MAF lists 131 somatic variants for this specimen: 56 protein-altering or splice-affecting, 26 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 26, Silent 26, Intron 9, 5'UTR 5, 3'Flank 5, RNA 3, Nonsense Mutation 2, 5'Flank 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 44/209 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGRN | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.81); catalogued as rs1427406777; called by muse, mutect2, varscan2
- BRPF1 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318897338, COSV100121193; called by muse, mutect2, varscan2
- CDK13 | c.1064T>A p.L355Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs764014601; called by muse, mutect2, varscan2
- CST9L | c.230G>A p.W77* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as rs1369684458; called by muse, mutect2, varscan2
- DUSP2 | c.392G>C p.G131A | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779039146, COSV56620526; called by muse, mutect2, varscan2
- DYRK1B | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as CM145256; called by muse, mutect2, varscan2
- GLDC | c.2780G>A p.R927Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs934940369; called by muse, mutect2
- IGLV4-69 | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs750808669; called by muse, varscan2
- KDR | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55769015; called by muse, mutect2, varscan2
- LRP1B | c.5426G>A p.R1809K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV67208217; called by muse, mutect2, varscan2
- MISP | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs772192185; called by muse, mutect2, varscan2
- OR4A16 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV59044626; called by muse, mutect2, varscan2
- PGBD1 | c.2182A>G p.I728V | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.193); catalogued as rs1244577240; called by muse, mutect2, varscan2
- PTPRD | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV61930344, COSV61947533; called by muse, mutect2, varscan2
- RPE65 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs867808254; called by muse, mutect2
- ZNF439 | c.1354C>G p.Q452E | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV58310865; called by muse, mutect2, varscan2
- AL592490.1 | c.1584C>A p.D528E | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP10A | c.740+1G>A p.X247_splice | Splice Site (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- ATP7A | c.2660G>C p.S887T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- ATR | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- B4GALNT3 | c.2449G>T p.D817Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BABAM2 | c.1040A>C p.Y347S | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- BHMG1 | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- BLK | c.708C>G p.I236M | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- BRD3 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- C4orf54 | c.5107G>C p.G1703R | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- CPAMD8 | c.3002C>T p.S1001F (on ENST00000651564; = p.S954F on NM_015692.5) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX3X | c.1921T>G p.F641V (on ENST00000399959; = p.F642V on NM_001356.5) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- DNAH9 | c.10396G>A p.V3466I | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ECT2 | c.1478T>A p.L493H (on ENST00000392692 / NM_001349098.2; = p.L462H on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83H | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- GDF3 | c.882T>A p.H294Q | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- GPATCH8 | c.4131T>A p.H1377Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HTR2C | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV3-43 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.286); called by muse, mutect2
- IGLV7-46 | c.170T>C p.F57S | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LAMB2 | c.2086G>A p.V696I | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- LINGO2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MCOLN3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- MROH6 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NRAP | c.2324G>C p.R775P (on ENST00000359988 / NM_001322945.2; = p.R740P on NM_006175.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NUMA1 | c.2962C>G p.L988V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ONECUT3 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PCDH1 | c.1346G>A p.G449D | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PDCL2 | c.679A>T p.I227F | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- PIP4P1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- RO60 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAMD9 | c.2812dup p.C938Lfs*2 | Frame Shift Ins (INS) | VAF 57/156 reads (37%) | called by mutect2, pindel, varscan2
- SETD7 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SNX25 | c.61T>A p.Y21N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31D1 | c.3571G>A p.V1191I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TINF2 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- TSC2 | c.5070C>T p.D1690= | Splice Region (SNP) | VAF 56/102 reads (55%) | called by muse, mutect2, varscan2
- YLPM1 | c.3364_3365del p.R1122Gfs*9 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | called by pindel, varscan2
- ZNF296 | c.160A>G p.K54E | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AC005833.1 | c.1479G>A p.A493= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs192391682, COSV52902193, COSV52902311, COSV99362661; called by muse, mutect2, varscan2
- ACVR1B | c.927G>A p.L309= | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- ATP2C2 | c.2130T>C p.D710= | Silent (SNP) | VAF 36/63 reads (57%) | catalogued as rs773228361; called by muse, mutect2, varscan2
- C19orf38 | c.255C>T p.P85= | Silent (SNP) | VAF 21/151 reads (14%) | called by muse, mutect2, varscan2
- CHAMP1 | c.1176T>A p.S392= | Silent (SNP) | VAF 35/300 reads (12%) | called by muse, mutect2, varscan2
- CLNK | c.519C>T p.Y173= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- DNAH11 | c.6780C>T p.G2260= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs377115580; called by mutect2, varscan2
- DOCK5 | c.3639A>G p.Q1213= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1189020243, COSV52398947; called by muse, mutect2, varscan2
- FAM71C | c.672C>T p.H224= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as rs139736567; called by muse, mutect2, varscan2
- IGLV4-69 | c.309G>A p.Q103= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as rs555171423; called by muse, varscan2
- JAKMIP2 | c.1491G>A p.E497= | Silent (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- KMT2C | c.14688G>A p.K4896= | Silent (SNP) | VAF 40/132 reads (30%) | called by muse, mutect2, varscan2
- KRTAP10-1 | c.33C>T p.S11= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs782024403; called by muse, mutect2, varscan2
- MUC4 | c.510A>T p.S170= | Silent (SNP) | VAF 38/139 reads (27%) | called by muse, mutect2, varscan2
- MYT1L | c.3408G>A p.P1136= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs780878610, COSV101216728; called by muse, varscan2
- OR52I2 | c.135G>A p.V45= | Silent (SNP) | VAF 58/128 reads (45%) | called by muse, mutect2, varscan2
- RAI14 | c.2607C>T p.Y869= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs753134774, COSV54292294; called by muse, mutect2, varscan2
- RGS6 | c.348G>A p.P116= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs770859468, COSV59563748; called by muse, mutect2, varscan2
- SHE | c.544C>T p.L182= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs1408858322; called by muse, mutect2, varscan2
- SIX5 | c.2076C>T p.T692= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs146790068; called by muse, mutect2, varscan2
- SKAP2 | c.165A>G p.V55= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- SMCR8 | c.2097C>T p.S699= | Silent (SNP) | VAF 41/153 reads (27%) | catalogued as rs779352626, COSV100329419; called by muse, mutect2, varscan2
- TAF3 | c.1125T>C p.N375= | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.2613A>T p.P871= | Silent (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2, varscan2
- ULK2 | c.1653C>T p.C551= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- VPS37A | c.39C>G p.S13= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs775592742; called by muse, mutect2, varscan2
- BTN3A1 | c.*360G>C | 3'UTR (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2
- C11orf86 | c.*686G>A | 3'UTR (SNP) | VAF 21/68 reads (31%) | catalogued as rs928035426; called by muse, mutect2, varscan2
- CAV2 | c.*1663A>G | 3'UTR (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- CDS2 | c.*2733T>G | 3'UTR (SNP) | VAF 23/161 reads (14%) | called by muse, mutect2, varscan2
- CHL1 | chr3:407120 A>G | 3'Flank (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- CLNK | c.*3504A>C | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, varscan2
- CRYBG2 | c.-17G>C | 5'UTR (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- CST9 | c.-33A>G | 5'UTR (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2430+52A>T | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2
- CYP2U1 | c.*1934A>G | 3'UTR (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- CYP8B1 | c.*1526G>A | 3'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- DCHS2 | n.584G>A | RNA (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- DHX8 | c.*55T>C | 3'UTR (SNP) | VAF 6/25 reads (24%) | catalogued as rs879206378; called by muse, mutect2, varscan2
- EMX2 | c.-268A>G | 5'UTR (SNP) | VAF 20/96 reads (21%) | called by muse, varscan2
- FABP7 | c.348+271T>C | Intron (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2, varscan2
- FAM120A | c.1734+613T>C | Intron (SNP) | VAF 21/43 reads (49%) | catalogued as rs975783620; called by muse, mutect2, varscan2
- GAPVD1 | c.*2036A>G | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- HOXB9 | c.*1145T>C | 3'UTR (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- HYAL1 | c.-121C>T | 5'UTR (SNP) | VAF 35/66 reads (53%) | catalogued as rs1434878136; called by muse, mutect2, varscan2
- IL13 | c.*189C>T | 3'UTR (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- IL16 | chr15:81309682 ins AAGCACC | 3'Flank (INS) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- IRX2 | c.*600C>G | 3'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- KHDRBS1 | c.*479A>C | 3'UTR (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- LINC01553 | n.4252A>G | RNA (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- LYPD1 | c.-245G>A | 5'UTR (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- MAP4 | c.2000-13729G>A | Intron (SNP) | VAF 12/95 reads (13%) | catalogued as rs1318672852, COSV99275060; called by muse, mutect2, varscan2
- MOB3B | c.*2791T>C | 3'UTR (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- MS4A1 | c.*952T>C | 3'UTR (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- NAA30 | c.*304A>T | 3'UTR (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- NTRK2 | c.1397-55559G>A | Intron (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- OSGIN1 | n.830G>A | RNA (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- PCDH15 | c.*2267T>C | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- PID1 | chr2:229025148 G>A | 3'Flank (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*5785T>C | 3'UTR (SNP) | VAF 11/74 reads (15%) | catalogued as rs1213276866; called by muse, mutect2, varscan2
- PRKRA | c.317+54G>C | Intron (SNP) | VAF 20/44 reads (45%) | called by mutect2, varscan2
- PSMB2 | c.*1386A>G | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- RNMT | c.*1910T>A | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- SDC2 | c.*1377A>G | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- SEMA5B | c.1136+23C>T | Intron (SNP) | VAF 9/75 reads (12%) | catalogued as rs764571668; called by muse, mutect2, varscan2
- SHROOM2 | c.*1552T>C | 3'UTR (SNP) | VAF 21/22 reads (95%) | called by muse, mutect2, varscan2
- SLC45A4 | c.*902C>T | 3'UTR (SNP) | VAF 21/62 reads (34%) | catalogued as rs902938037; called by muse, mutect2, varscan2
- SLC9A2 | c.*2109A>C | 3'UTR (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- SNX13 | c.441-4619C>T | Intron (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- TMEM25 | c.*824G>C | 3'UTR (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- TRA2A | chr7:23532025 A>G | 5'Flank (SNP) | VAF 25/115 reads (22%) | catalogued as rs1033509572; called by muse, mutect2, varscan2
- ZBTB26 | chr9:122917834 A>G | 3'Flank (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- ZBTB38 | chr3:141447904 G>T | 3'Flank (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- ZNF33A | c.*1563A>T | 3'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- ZSCAN9 | c.568+1335_568+1339del | Intron (DEL) | VAF 12/76 reads (16%) | called by pindel, varscan2
